Surgical pathology report (de-identified scan), TCGA case TCGA-33-AASI, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-AASI-01A (Primary Tumor).

[page 1 of 6]
██
██

=====

INTERPRETATION AND DIAGNOSIS:

- 1) 4R LYMPH NODE (RESECTION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
- 2) 9L LYMPH NODE (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
- 3) L10 LYMPH NODE (EXCISION) THREE (3) LYMPH NODES AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
- 4) STATION 7 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
- 5) LEFT LOWER LOBE (LOBECTOMY):

SPECIMEN TYPE:
Lobectomy

TUMOR SITE:
Left lower lobe

HISTOLOGIC TYPE:
Squamous cell carcinoma

TUMOR SIZE:
Greatest dimension: 7.0 cm

HISTOLOGIC GRADE:
G2: Moderately differentiated

LYMPH NODES (ALL PARTS):
Direct extension of carcinoma in 2 of 21 lymph nodes

EXTENT OF INVASION (STAGING):
pT2: Tumor which is greater than 3 cm.

REGIONAL LYMPH NODES:
pN1: Metastasis in ipsilateral peribronchial, hilar or intrapulmonary nodes, including those involved by direct extension

(Continued on next page.)

ICD-O-3
Carcinoma, squamous cell NOS 8070/3
Site @ Lung, lower lobe C84.1
5/28/14

[page 2 of 6]
SURGICAL
PATHOLOGY

=====

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS (CHECK ALL THAT APPLY):

Carcinoma is present in tissue subjacent to the staple line.
Vascular and bronchial margins negative for tumor.

VENOUS/ARTERIAL (LARGE VESSEL) INVASION:

Absent

LYMPHATIC (SMALL VESSEL) INVASION:

Absent

ADDITIONAL PATHOLOGIC FINDINGS (CHECK ALL THAT APPLY):

Emphysematous changes

6) STATION 6 (EXCISION): TWO (2) LYMPH NODES AND ASSOCIATED
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

NOTE: This case was shown at the

*Electronic signature

=====

Clinical History:

H/O LUNG CANCER.

GROSS DESCRIPTION

(Continued on next page.)

[page 3 of 6]
SURGICAL
PATHOLOGY

PART #1: FS: 4R LYMPH NODE
Resident Pathologist:

FROZEN SECTION DIAGNOSIS:

Staff Pathologist:

Other Pathologists / PAs:

4R Lymph Node: Twelve (12) fragments of lymphoid tissue, negative for tumor on representative frozen sections.

Dictated by:

The specimen is received fresh labeled with the patient's name, [REDACTED], and designated "4R lymph node". It consists of twelve (12) pieces of pale tan white pink fragmented soft tissue measuring in aggregate approximately from 0.1 to 0.2 cm x 0.1 x 0.2 cm. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS:

1 - FSC - M
1 - TOTAL - M

PART #2: 9-L LYMPH NODE
Resident Pathologist:

Dictated by:

The specimen is received fresh, labeled [REDACTED] and designated as 9L lymph node. The specimen consists of one piece of pale tan, red-brown soft tissue, measuring approximately 2.2 x 1.4 x 1.0 cm. Approximately 50% of this specimen is submitted for possible future studies and 50% is submitted for histology.

SUMMARY OF SECTIONS:

1 - A - 1
1 - TOTAL - 1

(Continued on next page.)

[page 4 of 6]
SURGICAL
PATHOLOGY

=====

PART #3: L-10 LYMPH NODE
Resident Pathologist:

Dictated by:

The specimen is received fresh, labeled [REDACTED] and designated as level 10 lymph node. The specimen consists of 3 pieces of red-tan-brown soft tissue, measuring 2.2 x 1.8 x 0.8 cm. Three possible lymph nodes are identified, after serial sectioning. The largest possible lymph node is serially sectioned to reveal a pale tan cut surface. 25% of this is submitted for possible future studies and 75% of the specimen is submitted for histology.

SUMMARY OF SECTIONS:

- 1 - A - 1 (1/2 LARGEST LYMPH NODE)
- 1 - B - 2 (POSSIBLE LYMPH NODES)
- 1 - C - 1 (SUBMITTED IN LENS PAPER, POSSIBLE LYMPH NODES)
- 3 - TOTAL - 4

PART #4: STATION 7
Resident Pathologist:

Dictated by:

The specimen is received fresh, labeled [REDACTED] and designated as station 7. The specimen consists of one piece of red-tan-brown soft tissue, measuring approximately 1.5 x 1.0 x 0.9 cm. The tissue representative possible lymph nodes. 50% of it is submitted for future possible studies, and 50% of it is submitted for histology.

SUMMARY OF SECTIONS:

- 1 - A - 1
- 1 - TOTAL - 1

(Continued on next page.)

[page 5 of 6]
SURGICAL
PATHOLOGY

PART #5: LEFT LOWER LOBE
Resident Pathologist:

Dictated by:

The specimen is received fresh, labeled [REDACTED] and designated left lower lobe. The specimen consists of a 14.5 x 10.0 x 3.5 cm piece of pale pink, tan soft tissue that grossly is identifiable as a lobe of lung. The specimen weighs 152 grams. The specimen is perfused with formalin and the pleural surfaces are inked black. The specimen contains one staple line, measuring approximately 2 cm and one vascular margin that is stapled, that measures approximately 2.5 cm. The bronchial margins, vascular margins and the staple margins are removed and submitted. Serial sectioning through the specimen reveals a pale tan firm, pink colored lesion, that measures approximately 7.0 x 6.5 x 3.5 cm. This lesions appears to be approximately 3 mm from the nearest pleural surface. Approximately 8 possible lymph nodes are identified, and representative sections are submitted.

SUMMARY OF SECTIONS:

1 - A - 1 (BRONCHIAL MARGIN)
1 - B - M (VASCULAR MARGIN)
1 - C - 1 (STAPLE LINE)
11 - D - N - 1/EA (LESION)
1 - O - 1 (NORMAL LUNG)
1 - P - 2 (TWO LYMPH NODES)
1 - Q - 3 (THREE LYMPH NODES)
1 - R - 3 (THREE LYMPH NODES)
1 - S - 1 (ONE LYMPH NODE)
19 - TOTAL - MULTIPLE

(Continued on next page.)

[page 6 of 6]
SURGICAL
PATHOLOGY

PART #6: STATION 6
Resident Pathologist:

Dictated by:

The specimen is received, labeled [REDACTED] and designated as station 6. The specimen consists of 2 pieces of tan, brown, gray soft tissue, measuring approximately 0.8 x 0.4 x 0.4 cm and may represent possible lymph nodes. The specimen is wrapped in lens paper and submitted in its entirety.

SUMMARY OF SECTIONS:

1 - A - 2
1 - TOTAL - 2

Other Surgical Pathology Specimens known to the computer: [REDACTED]

(End of Report)

printed

Source: NCI Genomic Data Commons file e651a61f-3662-4b78-942a-f028ef960f60 (TCGA-33-AASI.A04F5C2E-6BDB-425D-9A4B-B5FDE0BC0EE9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).